Somatic mutation profile of tumor specimen TCGA-J2-A4AD-01A (aliquot TCGA-J2-A4AD-01A-11D-A24D-08) from TCGA case TCGA-J2-A4AD, project TCGA-LUAD (Lung Adenocarcinoma). Sex at birth: female; Vital status: Dead; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Upper lobe, lung; AJCC pathologic stage: Stage IA; Age at diagnosis: 61.4 years (22,414 days).
Specimen TCGA-J2-A4AD-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 1af3a5e1-1558-49b0-b946-2ed353f93fa2.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-J2-A4AD-10A (Blood Derived Normal), aliquot TCGA-J2-A4AD-10A-01D-A24F-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/308349b2-11c8-4cf8-bd42-c7f7ec2667a3

The open-access MAF lists 356 somatic variants for this specimen: 256 protein-altering or splice-affecting, 87 silent, 13 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 218, Silent 87, Nonsense Mutation 17, Frame Shift Del 8, Splice Site 6, RNA 5, Intron 4, 3'UTR 4, Nonstop Mutation 3, In Frame Del 2, Splice Region 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- FLVCR1 | c.1093-1G>A p.X365_splice | Splice Site (SNP) | VAF 13/119 reads (11%) | catalogued as rs1057520666; ClinVar: pathogenic; called by muse, mutect2, varscan2
- NFE2L2 | c.101_109del p.R34_F37delinsL | In Frame Del (DEL) | VAF 12/50 reads (24%) | hotspot (GDC flag); called by mutect2, pindel, varscan2
- TP53 | c.715A>G p.N239D | Missense Mutation (SNP) | VAF 17/45 reads (38%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as rs876660807, COSV52664075, COSV52685174, COSV52979974, COSV53345856; ClinVar: likely pathogenic / uncertain significance; called by muse, mutect2, varscan2
- ABCA5 | c.250G>A p.V84M | Missense Mutation (SNP) | VAF 13/58 reads (22%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.559); catalogued as COSV101201292; called by muse, mutect2, varscan2
- ACOT9 | c.1262A>G p.H421R | Missense Mutation (SNP) | VAF 8/42 reads (19%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.685); catalogued as COSV100321466; called by muse, mutect2, varscan2
- ACTRT1 | c.320T>G p.L107R | Missense Mutation (SNP) | VAF 19/418 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV64418999, COSV64419064; called by muse, mutect2
- ADAMTS6 | c.2758C>T p.R920C | Missense Mutation (SNP) | VAF 14/122 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.973); catalogued as COSV100068624; called by muse, mutect2, varscan2
- ADCK1 | c.946G>C p.V316L | Missense Mutation (SNP) | VAF 21/73 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (0.919); catalogued as COSV99452693; called by muse, mutect2, varscan2
- ADGRD1 | c.1480A>G p.K494E | Missense Mutation (SNP) | VAF 9/99 reads (9%) | SIFT tolerated (0.68); PolyPhen benign (0); catalogued as COSV99897138; called by muse, mutect2
- AFF2 | c.681A>C p.E227D | Missense Mutation (SNP) | VAF 36/294 reads (12%) | SIFT tolerated (0.75); PolyPhen benign (0.003); catalogued as COSV100651255; called by muse, mutect2, varscan2
- AGO2 | c.1698G>C p.K566N | Missense Mutation (SNP) | VAF 8/92 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99596472; called by muse, mutect2
- AKR7A3 | c.813G>T p.M271I | Missense Mutation (SNP) | VAF 11/78 reads (14%) | SIFT tolerated (0.33); PolyPhen benign (0.06); catalogued as COSV100853836; called by muse, mutect2, varscan2
- AMER1 | c.739C>G p.P247A | Missense Mutation (SNP) | VAF 28/180 reads (16%) | SIFT tolerated (0.78); PolyPhen benign (0.055); catalogued as COSV100367082; called by muse, mutect2, varscan2
- AMPD3 | c.316A>G p.M106V (on ENST00000396553 / NM_001025389.2; = p.M115V on NM_000480.3) | Missense Mutation (SNP) | VAF 81/261 reads (31%) | SIFT tolerated (0.3); PolyPhen benign (0); catalogued as rs767030558, COSV101158262; called by muse, mutect2, varscan2
- APBA3 | c.476C>G p.S159C | Missense Mutation (SNP) | VAF 15/39 reads (38%) | SIFT tolerated (0.08); PolyPhen benign (0.001); catalogued as COSV100349784; called by muse, mutect2, varscan2
- APOLD1 | c.779A>G p.K260R (on ENST00000326765 / NM_001130415.2; = p.K229R on NM_030817.3) | Missense Mutation (SNP) | VAF 12/80 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.005); catalogued as COSV100458903; called by muse, mutect2, varscan2
- ARHGEF6 | c.29G>C p.W10S | Missense Mutation (SNP) | VAF 22/102 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV99166744; called by muse, mutect2, varscan2
- ARMCX2 | c.49G>C p.G17R | Missense Mutation (SNP) | VAF 10/100 reads (10%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.996); catalogued as COSV100168313; called by muse, mutect2, varscan2
- ARNT | c.664C>G p.R222G | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.986); catalogued as COSV100591098, COSV100591400; called by muse, mutect2, varscan2
- ATP10D | c.1505G>T p.R502M | Missense Mutation (SNP) | VAF 14/100 reads (14%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.95); catalogued as COSV99906202; called by muse, mutect2, varscan2
- ATP2B2 | c.80C>A p.T27K | Missense Mutation (SNP) | VAF 16/67 reads (24%) | SIFT deleterious (0); PolyPhen benign (0.182); catalogued as rs776820559, COSV100660512; called by muse, mutect2, varscan2
- ATP8B4 | c.499C>G p.L167V | Missense Mutation (SNP) | VAF 4/34 reads (12%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as COSV52723058, COSV99467623; called by muse, mutect2
- AXIN1 | c.188G>T p.R63L | Missense Mutation (SNP) | VAF 13/41 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs759464398, COSV99249418, COSV99250343; called by muse, mutect2, varscan2
- BCAN | c.885T>G p.D295E | Missense Mutation (SNP) | VAF 21/172 reads (12%) | SIFT tolerated (0.07); PolyPhen benign (0.314); catalogued as COSV100228513; called by muse, mutect2, varscan2
- BCLAF3 | c.818C>A p.S273* | Nonsense Mutation (SNP) | VAF 36/130 reads (28%) | catalogued as COSV100503395, COSV100503410; called by muse, mutect2, varscan2
- BCORL1 | c.5000C>A p.T1667N | Missense Mutation (SNP) | VAF 10/173 reads (6%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.523); catalogued as COSV99501023; called by muse, mutect2
- BLK | c.996G>T p.L332F | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.743); catalogued as COSV99377662; called by muse, mutect2
- BOD1L1 | c.5237G>C p.G1746A | Missense Mutation (SNP) | VAF 69/239 reads (29%) | SIFT deleterious (0.04); PolyPhen benign (0.433); catalogued as COSV99240477; called by muse, mutect2, varscan2
- BRPF3 | c.990G>C p.Q330H | Missense Mutation (SNP) | VAF 9/39 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100326200; called by muse, mutect2, varscan2
- C1orf141 | c.728C>A p.T243K | Missense Mutation (SNP) | VAF 20/60 reads (33%) | SIFT tolerated (0.27); PolyPhen benign (0.056); catalogued as COSV100924396; called by muse, varscan2
- C1orf226 | c.343C>T p.R115W | Missense Mutation (SNP) | VAF 31/52 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as rs1161488274, COSV100908183; called by muse, mutect2, varscan2
- C2CD3 | c.5838G>C p.E1946D | Missense Mutation (SNP) | VAF 23/204 reads (11%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.913); catalogued as COSV100487467; called by muse, mutect2, varscan2
- C2CD5 | c.547C>T p.R183C | Missense Mutation (SNP) | VAF 9/68 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.932); catalogued as rs1358127069, COSV61724153; called by muse, mutect2, varscan2
- C5orf51 | c.679G>C p.D227H | Missense Mutation (SNP) | VAF 10/114 reads (9%) | SIFT tolerated (0.14); PolyPhen benign (0.001); catalogued as COSV101069068; called by muse, mutect2
- CACNA1E | c.3362G>A p.R1121H | Missense Mutation (SNP) | VAF 4/10 reads (40%) | SIFT tolerated (0.08); PolyPhen benign (0.223); catalogued as rs370899738; called by muse, varscan2
- CADPS | c.1574C>G p.S525C | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99341084; called by muse, mutect2, varscan2
- CAMTA1 | c.4745G>A p.R1582Q | Missense Mutation (SNP) | VAF 24/386 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV57881130, COSV57916053; called by muse, mutect2
- CAPN7 | c.605A>G p.Q202R | Missense Mutation (SNP) | VAF 6/72 reads (8%) | SIFT tolerated (0.52); PolyPhen benign (0.074); catalogued as COSV53777759, COSV99513060; called by muse, mutect2
- CASS4 | c.1868A>G p.Q623R | Missense Mutation (SNP) | VAF 22/69 reads (32%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.773); catalogued as COSV100824938; called by muse, mutect2, varscan2
- CCDC88A | c.3261G>C p.Q1087H | Missense Mutation (SNP) | VAF 29/113 reads (26%) | SIFT deleterious (0); PolyPhen possibly damaging (0.81); catalogued as COSV99711235; called by muse, mutect2, varscan2
- CDAN1 | c.2908A>G p.T970A | Missense Mutation (SNP) | VAF 116/368 reads (32%) | SIFT tolerated (0.13); PolyPhen benign (0.079); catalogued as rs771026419, COSV100661450; called by muse, mutect2, varscan2
- CEP164 | c.701C>G p.S234* | Nonsense Mutation (SNP) | VAF 6/49 reads (12%) | catalogued as COSV99634444; called by muse, mutect2, varscan2
- CERKL | c.338G>T p.R113I | Missense Mutation (SNP) | VAF 3/41 reads (7%) | SIFT deleterious (0.01); PolyPhen benign (0.043); catalogued as COSV100184211; called by muse, mutect2
- CFAP65 | c.3117C>A p.D1039E | Missense Mutation (SNP) | VAF 42/188 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.005); catalogued as COSV100445962; called by muse, mutect2, varscan2
- CHEK2 | c.713G>A p.R238K (on ENST00000382580 / NM_001005735.2; = p.R195K on NM_007194.4) | Missense Mutation (SNP) | VAF 18/64 reads (28%) | SIFT tolerated (0.95); PolyPhen benign (0.003); catalogued as COSV100102541; called by muse, mutect2, varscan2
- CHERP | c.1902C>G p.I634M | Missense Mutation (SNP) | VAF 42/104 reads (40%) | SIFT tolerated (0.07); PolyPhen benign (0); catalogued as rs1353324989, COSV52223905, COSV52228109; called by muse, mutect2, varscan2
- CHODL | c.188G>T p.S63I | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT tolerated (0.3); PolyPhen benign (0.005); catalogued as COSV54732711; called by muse, mutect2, varscan2
- CLCN1 | c.2966G>C p.*989Sext*8 | Nonstop Mutation (SNP) | VAF 16/86 reads (19%) | catalogued as COSV100578561; called by muse, mutect2, varscan2
- CMAS | c.691C>T p.Q231* | Nonsense Mutation (SNP) | VAF 24/95 reads (25%) | catalogued as COSV99982742; called by muse, mutect2, varscan2
- CNKSR1 | c.1945C>G p.L649V (on ENST00000374253 / NM_001297647.2; = p.L642V on NM_006314.3) | Missense Mutation (SNP) | VAF 10/67 reads (15%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.991); catalogued as COSV100128525; called by muse, mutect2, varscan2
- CNOT4 | c.1945G>A p.A649T (on ENST00000541284 / NM_001190850.1; = p.A575T on NM_013316.4) | Missense Mutation (SNP) | VAF 58/170 reads (34%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.039); catalogued as rs759859047, COSV100836374; called by muse, mutect2, varscan2
- COG5 | c.2411T>C p.M804T (on ENST00000347053 / NM_001379512.1; = p.M825T on NM_006348.5 and 5 other RefSeq transcripts) | Missense Mutation (SNP) | VAF 41/79 reads (52%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as COSV99753607; called by muse, mutect2, varscan2
- COL11A1 | c.4000G>C p.D1334H | Missense Mutation (SNP) | VAF 10/115 reads (9%) | SIFT deleterious (0); PolyPhen possibly damaging (0.525); catalogued as COSV100618096, COSV62178220; called by muse, mutect2
- CREBBP | c.3160G>A p.E1054K | Missense Mutation (SNP) | VAF 29/151 reads (19%) | SIFT tolerated (0.05); PolyPhen benign (0.021); catalogued as COSV99270483; called by muse, mutect2, varscan2
- CSMD3 | c.13C>T p.R5C | Missense Mutation (SNP) | VAF 8/172 reads (5%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0); catalogued as COSV52176756; called by muse, mutect2
- CYTL1 | c.163G>A p.V55M | Missense Mutation (SNP) | VAF 6/47 reads (13%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.931); catalogued as COSV100312533; called by muse, mutect2, varscan2
- DCAF4L2 | c.587C>T p.A196V | Missense Mutation (SNP) | VAF 44/156 reads (28%) | SIFT tolerated (0.46); PolyPhen benign (0.233); catalogued as rs764483453, COSV60476507; called by muse, mutect2, varscan2
- DDX39B | c.1222G>C p.E408Q | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.478); catalogued as COSV100871093; called by muse, mutect2, varscan2
- DECR1 | c.835A>G p.N279D | Missense Mutation (SNP) | VAF 49/130 reads (38%) | SIFT deleterious (0.01); PolyPhen benign (0.409); catalogued as COSV99616579; called by muse, mutect2, varscan2
- DHX32 | c.769G>C p.E257Q | Missense Mutation (SNP) | VAF 38/135 reads (28%) | SIFT tolerated (0.38); PolyPhen benign (0.01); catalogued as COSV99501974; called by muse, mutect2, varscan2
- DHX32 | c.19G>T p.E7* | Nonsense Mutation (SNP) | VAF 7/134 reads (5%) | catalogued as COSV99501977; called by muse, mutect2
- DHX40 | c.287C>T p.S96L | Missense Mutation (SNP) | VAF 9/148 reads (6%) | SIFT tolerated (0.07); PolyPhen benign (0.136); catalogued as COSV99233252; called by muse, mutect2
- DLX5 | c.442C>T p.Q148* | Nonsense Mutation (SNP) | VAF 31/156 reads (20%) | catalogued as COSV56033490; called by muse, mutect2, varscan2
- DNAH5 | c.6043C>G p.L2015V | Missense Mutation (SNP) | VAF 6/127 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.985); catalogued as COSV99454467; called by muse, mutect2
- DOCK7 | c.5183G>T p.R1728L (on ENST00000635253 / NM_001367561.1; = p.R1697L on NM_033407.3) | Missense Mutation (SNP) | VAF 10/50 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.115); catalogued as COSV99226095; called by muse, mutect2, varscan2
- DOCK8 | c.3002T>C p.M1001T | Missense Mutation (SNP) | VAF 45/96 reads (47%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV101210084; called by muse, mutect2, varscan2
- DSEL | c.3431C>T p.P1144L | Missense Mutation (SNP) | VAF 20/52 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.736); catalogued as COSV59491907; called by muse, mutect2, varscan2
- DTX3L | c.817A>C p.N273H | Missense Mutation (SNP) | VAF 19/75 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.557); catalogued as COSV99950157; called by muse, mutect2, varscan2
- EFCAB14 | c.1295G>C p.G432A | Missense Mutation (SNP) | VAF 21/117 reads (18%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.999); catalogued as COSV100905670; called by muse, mutect2, varscan2
- EHF | c.420G>A p.M140I | Missense Mutation (SNP) | VAF 10/93 reads (11%) | SIFT tolerated (0.42); PolyPhen benign (0); catalogued as COSV99141065; called by muse, mutect2, varscan2
- EHMT2 | c.1947C>A p.F649L | Missense Mutation (SNP) | VAF 31/108 reads (29%) | SIFT tolerated (0.06); PolyPhen benign (0.025); catalogued as COSV100977245; called by muse, mutect2, varscan2
- EHMT2 | c.1856C>T p.S619L | Missense Mutation (SNP) | VAF 35/117 reads (30%) | SIFT tolerated (0.09); PolyPhen benign (0.186); catalogued as COSV100977246; called by muse, mutect2, varscan2
- EIF4A2 | c.5C>T p.S2F | Missense Mutation (SNP) | VAF 41/131 reads (31%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.828); catalogued as rs764605841, COSV100125656, COSV60624675; called by muse, mutect2, varscan2
- ELAC1 | c.385C>G p.Q129E | Missense Mutation (SNP) | VAF 9/69 reads (13%) | SIFT tolerated (0.15); PolyPhen benign (0.137); catalogued as COSV99495038; called by muse, mutect2, varscan2
- ELF2 | c.427G>C p.E143Q (on ENST00000379550 / NM_001331036.2; = p.E83Q on NM_006874.4) | Missense Mutation (SNP) | VAF 25/116 reads (22%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.885); catalogued as COSV99643295; called by muse, mutect2, varscan2
- ELOVL3 | c.560T>C p.L187P | Missense Mutation (SNP) | VAF 28/99 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.988); catalogued as COSV100892845; called by muse, mutect2, varscan2
- EPHA2 | c.1394G>C p.R465P | Missense Mutation (SNP) | VAF 33/124 reads (27%) | SIFT tolerated (0.33); PolyPhen probably damaging (0.988); catalogued as COSV100626307; called by muse, mutect2, varscan2
- EPPK1 | c.1735G>A p.D579N | Missense Mutation (SNP) | VAF 6/21 reads (29%) | SIFT tolerated (1); PolyPhen benign (0.017); catalogued as rs564630517, COSV101599959, COSV73261442; called by muse, mutect2, varscan2
- ESYT1 | c.2155G>A p.E719K | Missense Mutation (SNP) | VAF 10/168 reads (6%) | SIFT deleterious (0); PolyPhen possibly damaging (0.492); catalogued as COSV99920337; called by muse, mutect2
- EYS | c.1078C>A p.P360T | Missense Mutation (SNP) | VAF 14/55 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.005); catalogued as COSV60997831; called by muse, mutect2, varscan2
- F13B | c.420G>A p.W140* | Nonsense Mutation (SNP) | VAF 9/81 reads (11%) | catalogued as COSV100803466; called by muse, mutect2, varscan2
- F13B | c.419G>C p.W140S | Missense Mutation (SNP) | VAF 9/81 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100803467; called by muse, mutect2, varscan2
- F8 | c.3993G>C p.K1331N | Missense Mutation (SNP) | VAF 16/191 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs35702375, COSV100812010; called by muse, mutect2
- FAM47B | c.901G>T p.E301* | Nonsense Mutation (SNP) | VAF 22/85 reads (26%) | catalogued as COSV100264655; called by muse, mutect2, varscan2
- FAM98A | c.596C>G p.A199G | Missense Mutation (SNP) | VAF 39/135 reads (29%) | SIFT tolerated (0.32); PolyPhen benign (0.082); catalogued as COSV53210743, COSV99479566; called by muse, mutect2, varscan2
- FLII | c.370G>A p.E124K | Missense Mutation (SNP) | VAF 8/78 reads (10%) | SIFT deleterious (0.05); PolyPhen possibly damaging (0.677); catalogued as COSV100493833; called by muse, mutect2, varscan2
- FMO4 | c.376G>C p.D126H | Missense Mutation (SNP) | VAF 30/565 reads (5%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.679); catalogued as COSV100882175, COSV63002022; called by muse, mutect2
- FOLH1 | c.1601G>T p.R534I | Missense Mutation (SNP) | VAF 17/132 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.802); catalogued as rs751608388, COSV57052806; called by muse, mutect2, varscan2
- FOXP2 | c.795G>C p.E265D | Missense Mutation (SNP) | VAF 7/58 reads (12%) | SIFT tolerated (0.8); PolyPhen possibly damaging (0.899); catalogued as COSV100647426, COSV63481875; called by muse, mutect2
- G6PC | c.919C>T p.H307Y | Missense Mutation (SNP) | VAF 18/194 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as COSV99520984; called by muse, varscan2
- GC | c.892G>C p.D298H | Missense Mutation (SNP) | VAF 6/64 reads (9%) | SIFT deleterious (0.04); PolyPhen benign (0); catalogued as COSV99910180; called by muse, varscan2
- GINM1 | c.954G>C p.E318D | Missense Mutation (SNP) | VAF 10/58 reads (17%) | SIFT tolerated (0.19); PolyPhen benign (0.009); catalogued as COSV100168026, COSV59502265; called by muse, mutect2
- GOLIM4 | c.708A>C p.Q236H | Missense Mutation (SNP) | VAF 44/136 reads (32%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100463509; called by muse, mutect2, varscan2
- HAND2 | c.487G>C p.E163Q | Missense Mutation (SNP) | VAF 23/66 reads (35%) | SIFT tolerated (0.08); PolyPhen benign (0.033); catalogued as rs200277716, COSV100854247, COSV64017962; called by muse, mutect2, varscan2
- HDAC6 | c.2511G>T p.M837I | Missense Mutation (SNP) | VAF 5/26 reads (19%) | SIFT tolerated (0.55); PolyPhen benign (0.015); catalogued as COSV100491282; called by muse, mutect2, varscan2
- HPD | c.598T>A p.Y200N | Missense Mutation (SNP) | VAF 18/63 reads (29%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100000235; called by muse, mutect2, varscan2
- HSD3B7 | c.918G>C p.Q306H | Missense Mutation (SNP) | VAF 33/105 reads (31%) | SIFT tolerated (0.08); PolyPhen benign (0.068); catalogued as COSV99288349; called by muse, mutect2, varscan2
- IGLV3-27 | c.244G>T p.G82C | Missense Mutation (SNP) | VAF 11/52 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs374807863; called by muse, mutect2, varscan2
- IGSF1 | c.2568C>G p.I856M | Missense Mutation (SNP) | VAF 28/240 reads (12%) | SIFT tolerated (0.25); PolyPhen benign (0.283); catalogued as rs766815289, COSV100812347; called by muse, mutect2
- IL4I1 | c.119C>A p.P40H | Missense Mutation (SNP) | VAF 36/104 reads (35%) | SIFT deleterious (0.04); PolyPhen benign (0.007); catalogued as COSV100352374; called by muse, mutect2, varscan2
- INSL3 | c.218G>A p.R73Q | Missense Mutation (SNP) | VAF 10/22 reads (45%) | SIFT tolerated (0.41); PolyPhen benign (0.056); catalogued as rs1228235146, COSV57953774; called by muse, mutect2, varscan2
- ISL1 | c.658C>T p.L220F | Missense Mutation (SNP) | VAF 15/41 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV57934633; called by muse, mutect2, varscan2
- ITGA4 | c.822A>T p.Q274H | Missense Mutation (SNP) | VAF 12/40 reads (30%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV99276840; called by muse, mutect2, varscan2
- KCNMB1 | c.103G>T p.V35F | Missense Mutation (SNP) | VAF 23/60 reads (38%) | SIFT deleterious (0); PolyPhen possibly damaging (0.473); catalogued as COSV99212086; called by muse, mutect2, varscan2
- KCTD19 | c.868G>T p.A290S | Missense Mutation (SNP) | VAF 35/182 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.957); catalogued as COSV100431241; called by muse, mutect2, varscan2
- KDM5A | c.4808C>G p.S1603C | Missense Mutation (SNP) | VAF 17/165 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.99); catalogued as COSV101239073; called by muse, mutect2, varscan2
- KIAA1109 | c.10298G>C p.G3433A | Missense Mutation (SNP) | VAF 10/68 reads (15%) | SIFT tolerated (0.46); PolyPhen probably damaging (0.995); catalogued as COSV52668181, COSV99176850; called by muse, mutect2, varscan2
- KIF15 | c.3443T>A p.F1148Y | Missense Mutation (SNP) | VAF 11/51 reads (22%) | SIFT tolerated (0.07); PolyPhen benign (0.058); catalogued as COSV100393280; called by muse, mutect2, varscan2
- KIF1B | c.5342C>T p.A1781V (on ENST00000377086 / NM_001365952.1; = p.A1735V on NM_015074.3) | Missense Mutation (SNP) | VAF 29/104 reads (28%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99824247; called by muse, mutect2, varscan2
- KIF9 | c.1380+1G>C p.X460_splice | Splice Site (SNP) | VAF 39/148 reads (26%) | catalogued as COSV99647051; called by muse, mutect2, varscan2
- KMT2A | c.7967G>C p.R2656P | Missense Mutation (SNP) | VAF 14/47 reads (30%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.007); catalogued as COSV100629950, COSV63283323; called by muse, mutect2, varscan2
- KMT2C | c.2471G>T p.G824V | Missense Mutation (SNP) | VAF 24/136 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs780852959, COSV100076770; called by muse, mutect2, varscan2
- KMT2C | c.2036G>A p.R679K | Missense Mutation (SNP) | VAF 27/75 reads (36%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs77325966; called by muse, mutect2, varscan2
- KNTC1 | c.2992G>C p.E998Q | Missense Mutation (SNP) | VAF 9/26 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.05); catalogued as COSV100338822, COSV61079789; called by muse, mutect2
- KNTC1 | c.3124G>A p.E1042K | Missense Mutation (SNP) | VAF 6/27 reads (22%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100338823; called by muse, mutect2, varscan2
- KRT78 | c.268C>A p.Q90K | Missense Mutation (SNP) | VAF 8/56 reads (14%) | SIFT tolerated (0.25); PolyPhen benign (0.212); catalogued as COSV100467651; called by muse, mutect2, varscan2
- LAMA4 | c.2782C>A p.P928T (on ENST00000230538 / NM_001105206.3; = p.P921T on NM_002290.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 25/97 reads (26%) | SIFT deleterious (0.01); PolyPhen probably damaging (1); catalogued as rs727505130, COSV100039514, COSV57898353; ClinVar: uncertain significance; called by muse, varscan2
- LDB2 | c.996C>A p.N332K | Missense Mutation (SNP) | VAF 30/203 reads (15%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.992); catalogued as rs748150349, COSV58771418; called by muse, mutect2, varscan2
- LRP10 | c.1549A>G p.N517D | Missense Mutation (SNP) | VAF 18/74 reads (24%) | SIFT deleterious (0.01); PolyPhen benign (0.393); catalogued as COSV100612517; called by muse, mutect2, varscan2
- LRP1B | c.344-1G>A p.X115_splice | Splice Site (SNP) | VAF 10/46 reads (22%) | catalogued as COSV101261421; called by muse, mutect2
- LRRC37B | c.640A>G p.K214E | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.708); catalogued as COSV100496540; called by muse, mutect2
- LRRIQ1 | c.3811G>C p.V1271L | Missense Mutation (SNP) | VAF 30/140 reads (21%) | SIFT tolerated (0.65); PolyPhen benign (0.014); catalogued as COSV101280718; called by muse, mutect2, varscan2
- MAGI2 | c.2670C>A p.Y890* | Nonsense Mutation (SNP) | VAF 20/65 reads (31%) | catalogued as COSV100836713, COSV62661837; called by muse, mutect2, varscan2
- MARCHF7 | c.139G>T p.D47Y | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.707); catalogued as COSV99373988, COSV99374151; called by muse, mutect2
- MARCO | c.1294C>T p.R432* | Nonsense Mutation (SNP) | VAF 16/146 reads (11%) | catalogued as rs757066247, COSV100503674, COSV100503881, COSV59054917; called by muse, mutect2, varscan2
- MATN2 | c.80C>T p.S27L | Missense Mutation (SNP) | VAF 13/29 reads (45%) | SIFT tolerated (0.37); PolyPhen benign (0.003); catalogued as rs778619387, COSV99647192; called by muse, mutect2, varscan2
- MCM2 | c.964C>T p.L322F | Missense Mutation (SNP) | VAF 9/131 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.991); catalogued as COSV99413496; called by muse, mutect2
- MIPEP | c.529C>T p.P177S | Missense Mutation (SNP) | VAF 79/177 reads (45%) | SIFT tolerated (0.22); PolyPhen benign (0.044); catalogued as COSV66300461; called by muse, mutect2, varscan2
- MRFAP1 | c.268G>C p.E90Q | Missense Mutation (SNP) | VAF 32/100 reads (32%) | SIFT tolerated (0.12); PolyPhen benign (0.319); catalogued as COSV100307700, COSV100307713; called by muse, mutect2, varscan2
- MTHFD1 | c.316G>C p.E106Q | Missense Mutation (SNP) | VAF 14/143 reads (10%) | SIFT tolerated (0.32); PolyPhen benign (0.015); catalogued as COSV99387412; called by muse, mutect2
- MTOR | c.1938G>C p.Q646H | Missense Mutation (SNP) | VAF 5/110 reads (5%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.948); catalogued as COSV100816699; called by muse, mutect2
- MTOR | c.1370A>G p.D457G | Missense Mutation (SNP) | VAF 34/123 reads (28%) | SIFT tolerated (0.39); PolyPhen benign (0.001); catalogued as COSV100816701; called by muse, mutect2, varscan2
- MXRA5 | c.4786G>C p.D1596H | Missense Mutation (SNP) | VAF 9/153 reads (6%) | SIFT tolerated (0.16); PolyPhen benign (0.003); catalogued as COSV99479411; called by muse, mutect2
- MXRA5 | c.3578C>A p.S1193* | Nonsense Mutation (SNP) | VAF 11/116 reads (9%) | catalogued as COSV99476550, COSV99479416; called by muse, mutect2
- MXRA5 | c.3577T>C p.S1193P | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs768204084, COSV99479421; called by muse, mutect2, varscan2
- MYCBP2 | c.10403G>C p.G3468A (on ENST00000357337; = p.G3506A on NM_015057.5) | Missense Mutation (SNP) | VAF 14/98 reads (14%) | SIFT tolerated (0.15); PolyPhen probably damaging (0.981); catalogued as COSV100631985; called by muse, mutect2, varscan2
- MYH4 | c.3073A>G p.T1025A | Missense Mutation (SNP) | VAF 24/213 reads (11%) | SIFT tolerated (0.08); PolyPhen benign (0.003); catalogued as COSV99702296; called by muse, mutect2, varscan2
- MYO10 | c.4547A>G p.N1516S | Missense Mutation (SNP) | VAF 13/64 reads (20%) | SIFT tolerated (0.24); PolyPhen benign (0.326); catalogued as COSV99946341; called by muse, mutect2
- MYOZ1 | c.892G>T p.E298* | Nonsense Mutation (SNP) | VAF 10/35 reads (29%) | catalogued as COSV100831948; called by muse, mutect2, varscan2
- NAGS | c.488T>A p.F163Y | Missense Mutation (SNP) | VAF 3/23 reads (13%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99518038; called by muse, mutect2
- NBEA | c.722C>T p.A241V | Missense Mutation (SNP) | VAF 13/17 reads (76%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as rs1478929230, COSV59791392; called by muse, mutect2, varscan2
- NCOR1 | c.289T>A p.S97T | Missense Mutation (SNP) | VAF 3/38 reads (8%) | SIFT tolerated (0.07); PolyPhen benign (0.118); catalogued as COSV99252260; called by muse, mutect2
- NEB | c.1492G>C p.D498H | Missense Mutation (SNP) | VAF 4/37 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.914); catalogued as COSV99428222; called by muse, mutect2
- NEXN | c.1052T>C p.M351T | Missense Mutation (SNP) | VAF 23/84 reads (27%) | SIFT deleterious (0.01); PolyPhen benign (0.075); catalogued as COSV100331443, COSV57355098; called by muse, mutect2, varscan2
- NIPBL | c.6761A>G p.D2254G | Missense Mutation (SNP) | VAF 27/72 reads (38%) | SIFT deleterious (0); PolyPhen benign (0.053); catalogued as COSV99242796; called by muse, mutect2, varscan2
- NMT1 | c.497G>C p.R166P | Missense Mutation (SNP) | VAF 7/49 reads (14%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as rs748432196, COSV51959725, COSV51962386; called by muse, mutect2, varscan2
- NOX1 | c.421C>T p.L141F | Missense Mutation (SNP) | VAF 44/285 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV54195697, COSV99471768; called by muse, mutect2, varscan2
- NPSR1 | c.819C>G p.I273M | Missense Mutation (SNP) | VAF 8/101 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.92); catalogued as COSV100707209; called by muse, mutect2
- NRAP | c.1762G>A p.E588K (on ENST00000359988 / NM_001322945.2; = p.E553K on NM_006175.4) | Missense Mutation (SNP) | VAF 9/87 reads (10%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.643); catalogued as COSV63493255; called by muse, mutect2
- OPRM1 | c.776T>C p.L259S | Missense Mutation (SNP) | VAF 32/114 reads (28%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.989); catalogued as COSV100002503; called by muse, mutect2, varscan2
- OPRM1 | c.777G>T p.L259F | Missense Mutation (SNP) | VAF 34/117 reads (29%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.989); catalogued as COSV100002513; called by muse, mutect2, varscan2
- OR10Q1 | c.112C>T p.L38F | Missense Mutation (SNP) | VAF 34/161 reads (21%) | SIFT deleterious (0.03); PolyPhen benign (0.172); catalogued as rs755512382, COSV100372409; called by muse, mutect2, varscan2
- OR4X1 | c.682T>G p.L228V | Missense Mutation (SNP) | VAF 8/87 reads (9%) | SIFT tolerated (0.09); PolyPhen benign (0.001); catalogued as COSV100186839; called by muse, mutect2
- OR5W2 | c.548C>G p.P183R | Missense Mutation (SNP) | VAF 27/110 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); catalogued as COSV100747757, COSV100747784; called by muse, mutect2, varscan2
- OR8U1 | c.623T>A p.I208N | Missense Mutation (SNP) | VAF 9/139 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.949); catalogued as COSV100164143; called by muse, mutect2
- OSBPL6 | c.64G>T p.A22S | Missense Mutation (SNP) | VAF 16/63 reads (25%) | SIFT tolerated, low confidence (0.2); PolyPhen benign (0.351); catalogued as COSV99508553; called by muse, mutect2, varscan2
- OXR1 | c.2279A>G p.D760G (on ENST00000442977 / NM_001198532.1; = p.D732G on NM_018002.3) | Missense Mutation (SNP) | VAF 29/149 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99861265; called by muse, mutect2, varscan2
- PC | c.623A>G p.H208R | Missense Mutation (SNP) | VAF 15/87 reads (17%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV100852351; called by muse, mutect2, varscan2
- PCDH10 | c.2137G>A p.D713N | Missense Mutation (SNP) | VAF 21/84 reads (25%) | SIFT tolerated (0.61); PolyPhen probably damaging (0.989); catalogued as COSV99994587; called by muse, mutect2, varscan2
- PCDHA9 | c.184C>T p.R62C | Missense Mutation (SNP) | VAF 62/161 reads (39%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.53); catalogued as COSV100970131; called by muse, mutect2, varscan2
- PCDHB7 | c.765C>A p.S255R | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0.02); PolyPhen benign (0.073); catalogued as COSV50772627, COSV99177434; called by muse, mutect2, varscan2
- PCDHB7 | c.766C>G p.P256A | Missense Mutation (SNP) | VAF 15/65 reads (23%) | SIFT deleterious, low confidence (0.01); PolyPhen probably damaging (0.974); catalogued as rs782509138, COSV99177435; called by muse, mutect2, varscan2
- PCF11 | c.2276C>A p.S759* | Nonsense Mutation (SNP) | VAF 10/124 reads (8%) | catalogued as COSV100019277; called by muse, mutect2
- PCK1 | c.1429C>A p.H477N | Missense Mutation (SNP) | VAF 18/86 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.543); catalogued as COSV100100987; called by muse, mutect2, varscan2
- PCNX3 | c.5527G>T p.G1843C | Missense Mutation (SNP) | VAF 6/12 reads (50%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV100856658; called by muse, mutect2, varscan2
- PCSK7 | c.431A>G p.H144R | Missense Mutation (SNP) | VAF 23/260 reads (9%) | SIFT tolerated (0.1); PolyPhen benign (0.023); catalogued as rs1409829667, COSV100309548; called by muse, mutect2
- PDZD2 | c.3242C>G p.S1081* | Nonsense Mutation (SNP) | VAF 53/318 reads (17%) | catalogued as COSV99226801; called by muse, mutect2, varscan2
- PIH1D2 | c.665C>G p.S222C | Missense Mutation (SNP) | VAF 19/240 reads (8%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.476); catalogued as COSV54776746, COSV99735619; called by muse, mutect2
- PIPOX | c.1172G>C p.*391Sext*23 | Nonstop Mutation (SNP) | VAF 8/60 reads (13%) | catalogued as COSV100038098, COSV60141346; called by muse, mutect2
- PKD1 | c.4390G>A p.E1464K | Missense Mutation (SNP) | VAF 7/94 reads (7%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.776); catalogued as COSV99239092; called by muse, mutect2
- PKD1L1 | c.6331A>T p.T2111S | Missense Mutation (SNP) | VAF 7/17 reads (41%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as COSV99221445; called by muse, mutect2, varscan2
- PLCB2 | c.1447G>T p.G483C | Missense Mutation (SNP) | VAF 21/69 reads (30%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.571); catalogued as rs1006178265, COSV99542681; called by muse, mutect2, varscan2
- PMFBP1 | c.2077C>A p.Q693K (on ENST00000537465; = p.Q688K on NM_031293.3) | Missense Mutation (SNP) | VAF 15/61 reads (25%) | SIFT tolerated (0.83); PolyPhen benign (0.005); catalogued as COSV99401558; called by muse, mutect2, varscan2
- PPP1R12C | c.1616A>G p.D539G | Missense Mutation (SNP) | VAF 28/69 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.984); catalogued as COSV99670383; called by muse, mutect2, varscan2
- PRICKLE1 | c.2128G>A p.E710K | Missense Mutation (SNP) | VAF 17/91 reads (19%) | SIFT tolerated (0.15); PolyPhen benign (0.003); catalogued as rs774624657, COSV100454274; called by muse, mutect2, varscan2
- PRICKLE2 | c.2442G>C p.Q814H (on ENST00000295902; = p.Q758H on NM_198859.4) | Missense Mutation (SNP) | VAF 17/62 reads (27%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); catalogued as COSV55764849, COSV55770161, COSV99898105; called by muse, mutect2, varscan2
- PTPRD | c.3294G>T p.R1098S | Missense Mutation (SNP) | VAF 36/92 reads (39%) | SIFT tolerated (0.47); PolyPhen benign (0.011); catalogued as COSV100647167; called by muse, mutect2, varscan2
- PTPRT | c.901G>T p.G301W | Missense Mutation (SNP) | VAF 8/46 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100630684, COSV61973061; called by muse, mutect2, varscan2
- PTPRU | c.1419G>T p.E473D | Missense Mutation (SNP) | VAF 6/34 reads (18%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.933); catalogued as COSV100113780; called by muse, mutect2, varscan2
- RANBP2 | c.1231G>T p.V411L | Missense Mutation (SNP) | VAF 76/310 reads (25%) | SIFT deleterious (0.03); PolyPhen benign (0); catalogued as COSV99313381; called by muse, mutect2, varscan2
- RBAK-RBAKDN | c.523C>T p.R175C | Missense Mutation (SNP) | VAF 10/57 reads (18%) | SIFT tolerated, low confidence (0.23); PolyPhen benign (0); catalogued as rs146417655; called by muse, mutect2, varscan2
- RDH11 | c.49C>G p.L17V | Missense Mutation (SNP) | VAF 9/30 reads (30%) | SIFT tolerated (0.17); PolyPhen probably damaging (0.987); catalogued as COSV101191534; called by muse, mutect2, varscan2
- RHBDD2 | c.180T>G p.V60= | Splice Region (SNP) | VAF 31/128 reads (24%) | catalogued as COSV99138592; called by muse, mutect2, varscan2
- RIMBP2 | c.2925+1G>T p.X975_splice | Splice Site (SNP) | VAF 94/373 reads (25%) | catalogued as COSV99900610; called by muse, mutect2, varscan2
- RIMBP2 | c.2925G>T p.E975D | Missense Mutation (SNP) | VAF 95/375 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV99900614; called by muse, mutect2, varscan2
- RPS6KA1 | c.843G>A p.M281I | Missense Mutation (SNP) | VAF 3/10 reads (30%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.596); catalogued as COSV100837993; called by muse, mutect2
- RPTN | c.1415G>T p.S472I | Missense Mutation (SNP) | VAF 195/1278 reads (15%) | SIFT tolerated (0.09); PolyPhen benign (0.037); catalogued as COSV100285811; called by muse, mutect2, varscan2
- RYR2 | c.7049C>A p.A2350D | Missense Mutation (SNP) | VAF 24/42 reads (57%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV100773075; called by muse, mutect2, varscan2
- RYR3 | c.2912C>T p.S971F | Missense Mutation (SNP) | VAF 11/123 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.972); catalogued as COSV101214691; called by muse, mutect2
- SBF2 | c.2529G>C p.M843I | Missense Mutation (SNP) | VAF 24/137 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.884); catalogued as COSV99815834; called by muse, mutect2, varscan2
- SCN3A | c.3325G>C p.E1109Q | Missense Mutation (SNP) | VAF 22/99 reads (22%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.932); catalogued as COSV99328602; called by muse, mutect2, varscan2
- SEMG2 | c.931A>C p.K311Q | Missense Mutation (SNP) | VAF 29/95 reads (31%) | SIFT tolerated (0.45); PolyPhen probably damaging (0.964); catalogued as COSV101034245; called by muse, mutect2, varscan2
- SEPTIN3 | c.606C>G p.I202M | Missense Mutation (SNP) | VAF 14/108 reads (13%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.913); catalogued as COSV99352404; called by muse, mutect2, varscan2
- SLC11A1 | c.677G>C p.R226P | Missense Mutation (SNP) | VAF 8/24 reads (33%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.463); catalogued as rs1007528005, COSV99262502; called by muse, mutect2, varscan2
- SLC28A2 | c.1709C>A p.T570K | Missense Mutation (SNP) | VAF 6/52 reads (12%) | SIFT deleterious (0); PolyPhen possibly damaging (0.904); catalogued as rs762931759, COSV100754823; called by mutect2, varscan2
- SLC34A2 | c.113-1G>T p.X38_splice | Splice Site (SNP) | VAF 12/221 reads (5%) | catalogued as COSV101158462; called by muse, mutect2
- SLC34A2 | c.113C>T p.T38I | Missense Mutation (SNP) | VAF 12/222 reads (5%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as COSV101158463; called by muse, mutect2
- SLC6A2 | c.156C>A p.D52E | Missense Mutation (SNP) | VAF 33/116 reads (28%) | SIFT tolerated (1); PolyPhen benign (0); catalogued as rs1395219019, COSV99574650; called by muse, mutect2, varscan2
- SLC9A3 | c.770T>A p.V257E | Missense Mutation (SNP) | VAF 67/139 reads (48%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV99376697; called by muse, mutect2, varscan2
- SMARCA4 | c.4084G>A p.E1362K | Missense Mutation (SNP) | VAF 9/19 reads (47%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.546); catalogued as COSV100759143; called by muse, mutect2
- SMG8 | c.505C>G p.L169V | Missense Mutation (SNP) | VAF 7/80 reads (9%) | SIFT tolerated (0.22); PolyPhen possibly damaging (0.51); catalogued as COSV99959083; called by muse, mutect2
- SNX29 | c.258C>G p.F86L | Missense Mutation (SNP) | VAF 5/55 reads (9%) | SIFT tolerated (0.09); PolyPhen probably damaging (0.97); catalogued as COSV101625463; called by muse, mutect2
- SORCS1 | c.1040C>T p.T347I | Missense Mutation (SNP) | VAF 9/55 reads (16%) | SIFT deleterious (0); PolyPhen benign (0.275); catalogued as COSV99550638; called by muse, mutect2, varscan2
- SRRM2 | c.3416A>C p.Q1139P | Missense Mutation (SNP) | VAF 26/116 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.043); catalogued as COSV100071547; called by muse, mutect2, varscan2
- STAG2 | c.2023G>C p.E675Q | Missense Mutation (SNP) | VAF 7/31 reads (23%) | SIFT tolerated (0.05); PolyPhen possibly damaging (0.864); catalogued as COSV99495488; called by muse, mutect2, varscan2
- SVIL | c.1027C>G p.Q343E | Missense Mutation (SNP) | VAF 7/74 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.097); catalogued as COSV100881559; called by muse, mutect2, varscan2
- SYDE2 | c.2329C>T p.Q777* | Nonsense Mutation (SNP) | VAF 13/38 reads (34%) | catalogued as COSV52317928; called by muse, mutect2, varscan2
- SYNE2 | c.17902G>C p.E5968Q | Missense Mutation (SNP) | VAF 9/54 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs756577484, COSV100648526; called by muse, mutect2, varscan2
- TAF3 | c.1834G>C p.E612Q | Missense Mutation (SNP) | VAF 9/62 reads (15%) | SIFT deleterious, low confidence (0.02); PolyPhen possibly damaging (0.522); catalogued as COSV100720516; called by muse, mutect2, varscan2
- TAS2R43 | c.282C>G p.F94L | Missense Mutation (SNP) | VAF 28/53 reads (53%) | SIFT tolerated (0.06); PolyPhen benign (0.028); catalogued as COSV101115655; called by muse, mutect2, varscan2
- TEX15 | c.6278G>C p.W2093S (on ENST00000256246; = p.W2476S on NM_001350162.2) | Missense Mutation (SNP) | VAF 11/67 reads (16%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99822159; called by muse, mutect2, varscan2
- THSD7B | c.3824G>T p.R1275L (on ENST00000272643; = p.R1273L on NM_001316349.2) | Missense Mutation (SNP) | VAF 12/135 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55689505, COSV55712143; called by muse, mutect2
- TMIGD2 | c.563-1G>A p.X188_splice | Splice Site (SNP) | VAF 37/72 reads (51%) | catalogued as COSV100010523; called by muse, mutect2, varscan2
- TMPRSS11F | c.1317G>C p.*439Yext*14 | Nonstop Mutation (SNP) | VAF 11/80 reads (14%) | catalogued as COSV100678832; called by mutect2, varscan2
- TP53 | c.169G>A p.D57N | Missense Mutation (SNP) | VAF 25/214 reads (12%) | SIFT tolerated (0.44); PolyPhen benign (0); catalogued as COSV53275803; called by muse, mutect2, varscan2
- TRIM28 | c.1654A>G p.I552V | Missense Mutation (SNP) | VAF 17/146 reads (12%) | SIFT tolerated (0.32); PolyPhen benign (0.017); catalogued as COSV99449458; called by muse, mutect2, varscan2
- TTC21B | c.2728G>T p.A910S | Missense Mutation (SNP) | VAF 21/94 reads (22%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as rs778319902, COSV99692908; called by muse, mutect2, varscan2
- TTN | c.48383T>G p.L16128R (on ENST00000591111; = p.L8704R on NM_003319.4) | Missense Mutation (SNP) | VAF 10/101 reads (10%) | PolyPhen possibly damaging (0.468); catalogued as COSV60156585; called by muse, mutect2, varscan2
- TUBA3D | c.181C>A p.H61N | Missense Mutation (SNP) | VAF 27/81 reads (33%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.059); catalogued as COSV100342952; called by muse, mutect2, varscan2
- TUBA3D | c.934T>C p.Y312H | Missense Mutation (SNP) | VAF 57/201 reads (28%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (1); catalogued as COSV100342956; called by muse, mutect2, varscan2
- TUBA3E | c.245C>G p.T82S | Missense Mutation (SNP) | VAF 25/174 reads (14%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0); catalogued as COSV99919947; called by muse, mutect2, varscan2
- UBR4 | c.6419C>A p.T2140N | Missense Mutation (SNP) | VAF 22/128 reads (17%) | SIFT tolerated (0.61); PolyPhen benign (0); catalogued as COSV100921946; called by muse, mutect2, varscan2
- UQCRB | c.124G>T p.E42* | Nonsense Mutation (SNP) | VAF 11/98 reads (11%) | catalogued as COSV54629113, COSV99749307; called by muse, mutect2, varscan2
- USP54 | c.3458G>C p.R1153T | Missense Mutation (SNP) | VAF 36/159 reads (23%) | SIFT tolerated, low confidence (0.09); PolyPhen benign (0.046); catalogued as COSV100357645; called by muse, mutect2, varscan2
- USP54 | c.2099C>T p.S700F | Missense Mutation (SNP) | VAF 7/50 reads (14%) | SIFT deleterious (0); PolyPhen possibly damaging (0.548); catalogued as COSV60448618; called by muse, varscan2
- VANGL1 | c.528A>T p.R176S | Missense Mutation (SNP) | VAF 56/188 reads (30%) | SIFT deleterious (0.04); PolyPhen benign (0.185); catalogued as COSV100049508; called by muse, mutect2, varscan2
- VEZT | c.931G>A p.E311K | Missense Mutation (SNP) | VAF 9/116 reads (8%) | SIFT tolerated (0.33); PolyPhen benign (0.305); catalogued as rs1174683872, COSV99704325; called by muse, mutect2
- VPS13B | c.6626G>T p.C2209F | Missense Mutation (SNP) | VAF 7/122 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.259); catalogued as COSV100663766; called by muse, mutect2
- VWA3B | c.3682T>C p.S1228P | Missense Mutation (SNP) | VAF 4/14 reads (29%) | SIFT deleterious, low confidence (0.05); PolyPhen probably damaging (0.916); catalogued as COSV101417896; called by mutect2, varscan2
- WBP11 | c.542C>G p.S181C | Missense Mutation (SNP) | VAF 8/91 reads (9%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.57); catalogued as COSV99660912; called by muse, mutect2
- WDR24 | c.1174G>C p.E392Q (on ENST00000248142; = p.E262Q on NM_032259.4) | Missense Mutation (SNP) | VAF 17/78 reads (22%) | SIFT tolerated (1); PolyPhen benign (0.013); catalogued as rs758470087, COSV99556019; called by muse, mutect2, varscan2
- WNK4 | c.725C>G p.S242W | Missense Mutation (SNP) | VAF 12/72 reads (17%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99519577; called by muse, mutect2, varscan2
- XRRA1 | c.1990C>G p.Q664E | Missense Mutation (SNP) | VAF 24/215 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.98); catalogued as COSV100213587; called by muse, mutect2, varscan2
- ZC3H4 | c.467G>C p.R156T | Missense Mutation (SNP) | VAF 13/117 reads (11%) | SIFT deleterious (0.01); PolyPhen benign (0.388); catalogued as rs780577981, COSV99452840; called by muse, mutect2, varscan2
- ZKSCAN1 | c.247C>T p.Q83* | Nonsense Mutation (SNP) | VAF 11/88 reads (13%) | catalogued as COSV100164370; called by muse, mutect2, varscan2
- ZNF208 | c.3559C>G p.H1187D | Missense Mutation (SNP) | VAF 14/39 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); catalogued as COSV101237213; called by muse, mutect2, varscan2
- ZNF267 | c.1208C>G p.T403S | Missense Mutation (SNP) | VAF 23/87 reads (26%) | SIFT tolerated (0.11); PolyPhen possibly damaging (0.891); catalogued as rs1461095469, COSV100339942; called by muse, mutect2, varscan2
- ZNF438 | c.1708G>T p.E570* | Nonsense Mutation (SNP) | VAF 46/135 reads (34%) | catalogued as COSV100062815; called by muse, mutect2, varscan2
- ZNF502 | c.85G>C p.E29Q | Missense Mutation (SNP) | VAF 27/98 reads (28%) | SIFT tolerated (0.15); PolyPhen benign (0.116); catalogued as COSV99939881; called by muse, mutect2, varscan2
- ZNF648 | c.296G>T p.G99V | Missense Mutation (SNP) | VAF 9/129 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.207); catalogued as COSV100374812; called by muse, mutect2
- ZNF808 | c.1765C>A p.H589N | Missense Mutation (SNP) | VAF 19/88 reads (22%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV100708228, COSV63119339; called by muse, mutect2, varscan2
- CNPPD1 | c.138_158del p.A47_E53del | In Frame Del (DEL) | VAF 12/114 reads (11%) | called by mutect2, pindel
- CSTF2T | c.410C>T p.P137L | Missense Mutation (SNP) | VAF 9/138 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- HEATR5A | c.1307del p.G436Afs*32 | Frame Shift Del (DEL) | VAF 15/58 reads (26%) | called by mutect2, pindel
- LUM | c.486del p.F163Sfs*9 | Frame Shift Del (DEL) | VAF 21/89 reads (24%) | called by mutect2, pindel, varscan2
- PRKCD | c.1645del p.H549Mfs*45 | Frame Shift Del (DEL) | VAF 9/38 reads (24%) | called by mutect2, pindel, varscan2
- PTPN20 | c.23G>T p.R8I | Missense Mutation (SNP) | VAF 32/528 reads (6%) | SIFT tolerated (0.14); PolyPhen benign (0.086); called by muse, mutect2
- SAP130 | c.2188G>C p.A730P | Missense Mutation (SNP) | VAF 12/146 reads (8%) | SIFT tolerated, low confidence (0.11); PolyPhen benign (0.001); called by muse, mutect2
- SEC61A1 | c.141+1del | Frame Shift Del (DEL) | VAF 52/221 reads (24%) | called by mutect2, pindel, varscan2
- SLC24A4 | c.1295_1314del p.P432Rfs*91 | Frame Shift Del (DEL) | VAF 17/90 reads (19%) | called by mutect2, pindel, varscan2
- TECPR2 | c.3009dup p.N1004Efs*17 | Frame Shift Ins (INS) | VAF 20/93 reads (22%) | called by mutect2, pindel, varscan2
- TRAV22 | c.78G>C p.Q26H | Missense Mutation (SNP) | VAF 7/88 reads (8%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); called by muse, mutect2
- XKR3 | c.1306C>G p.Q436E | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT deleterious, low confidence (0.05); PolyPhen benign (0.02); called by muse, mutect2, varscan2
- ZBTB14 | c.849del p.K284Rfs*9 | Frame Shift Del (DEL) | VAF 20/83 reads (24%) | called by mutect2, pindel, varscan2
- ZNF33B | c.1648del p.E550Rfs*47 | Frame Shift Del (DEL) | VAF 22/132 reads (17%) | called by mutect2, pindel, varscan2
- ZNF584 | c.1089del p.F363Lfs*87 | Frame Shift Del (DEL) | VAF 18/44 reads (41%) | called by mutect2, pindel, varscan2
- ABCA7 | c.5556G>T p.V1852= | Silent (SNP) | VAF 15/35 reads (43%) | catalogued as COSV99566694; called by muse, mutect2, varscan2
- ABCC9 | c.2157C>T p.L719= | Silent (SNP) | VAF 19/142 reads (13%) | catalogued as rs201848437, COSV53973502; ClinVar: likely benign; called by muse, mutect2, varscan2
- ANKMY1 | c.1845A>T p.A615= | Silent (SNP) | VAF 15/50 reads (30%) | catalogued as COSV99803306; called by muse, mutect2, varscan2
- ANKRD34A | c.546G>T p.T182= | Silent (SNP) | VAF 9/167 reads (5%) | catalogued as rs587648195, COSV100041419; called by muse, mutect2
- AP3D1 | c.3444G>A p.A1148= | Silent (SNP) | VAF 31/160 reads (19%) | catalogued as rs761320538, COSV61433314; called by muse, mutect2, varscan2
- BAG6 | c.1419G>A p.L473= | Silent (SNP) | VAF 4/45 reads (9%) | catalogued as COSV99277653; called by muse, mutect2
- BBS9 | c.2013A>C p.V671= (on ENST00000242067 / NM_001348036.1; = p.V631= on NM_014451.3 and 1 other RefSeq transcript) | Silent (SNP) | VAF 41/226 reads (18%) | catalogued as COSV99630230; called by muse, mutect2, varscan2
- BUD13 | c.1425C>T p.L475= | Silent (SNP) | VAF 46/187 reads (25%) | catalogued as rs546870931, COSV52770430; called by muse, mutect2, varscan2
- CCDC172 | c.117G>A p.K39= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as COSV100320017; called by muse, mutect2
- CD19 | c.39C>T p.L13= | Silent (SNP) | VAF 21/110 reads (19%) | catalogued as COSV100218277; called by muse, mutect2, varscan2
- CDH4 | c.2535C>T p.F845= | Silent (SNP) | VAF 14/60 reads (23%) | catalogued as COSV100849716; called by muse, mutect2, varscan2
- CDON | c.624A>C p.R208= | Silent (SNP) | VAF 8/179 reads (4%) | catalogued as COSV99702023; called by muse, mutect2
- CETN2 | c.384C>T p.R128= | Silent (SNP) | VAF 31/121 reads (26%) | catalogued as rs371059141, COSV100938691; called by muse, mutect2, varscan2
- CPAMD8 | c.3519C>T p.V1173= (on ENST00000651564; = p.V1126= on NM_015692.5) | Silent (SNP) | VAF 15/42 reads (36%) | catalogued as COSV71596391; called by muse, mutect2, varscan2
- DIP2B | c.1077G>A p.L359= | Silent (SNP) | VAF 14/46 reads (30%) | catalogued as COSV99999449; called by muse, mutect2, varscan2
- DMD | c.6918C>A p.S2306= | Silent (SNP) | VAF 11/35 reads (31%) | catalogued as COSV100629442; called by muse, mutect2, varscan2
- DNAH5 | c.10351T>C p.L3451= | Silent (SNP) | VAF 52/252 reads (21%) | catalogued as COSV99454466; called by muse, mutect2, varscan2
- DNAJC10 | c.66G>C p.L22= | Silent (SNP) | VAF 5/83 reads (6%) | catalogued as rs1222395163, COSV99899635; called by muse, mutect2
- EFCAB6 | c.2685C>T p.Y895= | Silent (SNP) | VAF 17/180 reads (9%) | catalogued as rs747787524, COSV53058273; called by muse, mutect2
- EHMT2 | c.1200C>G p.L400= | Silent (SNP) | VAF 6/17 reads (35%) | catalogued as COSV100977248; called by muse, mutect2, varscan2
- EIF2AK4 | c.3156G>A p.L1052= | Silent (SNP) | VAF 7/34 reads (21%) | catalogued as COSV99775402; called by muse, mutect2, varscan2
- EMSY | c.306G>A p.L102= | Silent (SNP) | VAF 12/81 reads (15%) | catalogued as COSV58266186; called by muse, mutect2, varscan2
- ENDOD1 | c.1502A>G p.*501= | Silent (SNP) | VAF 20/79 reads (25%) | catalogued as COSV99566844; called by muse, mutect2, varscan2
- EXOSC10 | c.34C>T p.L12= | Silent (SNP) | VAF 12/98 reads (12%) | catalogued as rs371902409; called by muse, mutect2, varscan2
- F8 | c.2250G>A p.L750= | Silent (SNP) | VAF 11/162 reads (7%) | catalogued as COSV100812013; called by muse, mutect2
- FAM161A | c.1437T>C p.D479= | Silent (SNP) | VAF 22/82 reads (27%) | catalogued as COSV100281555; called by muse, mutect2, varscan2
- GLI2 | c.1248C>T p.V416= (on ENST00000361492 / NM_001374353.1; = p.V433= on NM_005270.5 and 1 other RefSeq transcript) | Silent (SNP) | VAF 10/78 reads (13%) | catalogued as COSV100084388; called by muse, mutect2, varscan2
- GPR156 | c.2436G>C p.T812= | Silent (SNP) | VAF 78/334 reads (23%) | catalogued as COSV100251734, COSV59938055; called by muse, mutect2, varscan2
- GRAMD1B | c.1245A>T p.P415= | Silent (SNP) | VAF 3/19 reads (16%) | catalogued as COSV100455266; called by muse, mutect2
- GRPEL1 | c.489G>A p.L163= | Silent (SNP) | VAF 7/122 reads (6%) | catalogued as COSV99380783; called by muse, mutect2
- HCN1 | c.1968G>C p.P656= | Silent (SNP) | VAF 7/166 reads (4%) | catalogued as COSV57498699, COSV57511150; called by muse, mutect2
- HECW1 | c.3738T>C p.G1246= | Silent (SNP) | VAF 10/87 reads (11%) | catalogued as COSV101224353; called by muse, mutect2, varscan2
- HOOK1 | c.906G>A p.L302= | Silent (SNP) | VAF 25/123 reads (20%) | catalogued as COSV100968996; called by muse, mutect2, varscan2
- HOXB4 | c.727C>A p.R243= | Silent (SNP) | VAF 14/44 reads (32%) | catalogued as rs767904414, COSV100203855; called by muse, mutect2, varscan2
- HSPG2 | c.2511C>T p.A837= | Silent (SNP) | VAF 10/76 reads (13%) | catalogued as COSV101021272; called by muse, mutect2, varscan2
- IFNA8 | c.522C>T p.S174= | Silent (SNP) | VAF 76/212 reads (36%) | catalogued as COSV101206940; called by muse, varscan2
- KCNMB1 | c.102G>T p.L34= | Silent (SNP) | VAF 21/58 reads (36%) | catalogued as COSV99212108; called by muse, mutect2, varscan2
- KCTD8 | c.1260C>A p.S420= | Silent (SNP) | VAF 69/243 reads (28%) | catalogued as COSV100759292, COSV100760141; called by muse, mutect2, varscan2
- KNL1 | c.3777C>T p.L1259= (on ENST00000346991 / NM_170589.5; = p.L1233= on NM_144508.5) | Silent (SNP) | VAF 8/69 reads (12%) | catalogued as COSV100707084; called by muse, mutect2, varscan2
- LAMA2 | c.8619C>A p.P2873= | Silent (SNP) | VAF 24/91 reads (26%) | catalogued as COSV101370859; called by muse, mutect2, varscan2
- LRFN2 | c.1158C>A p.T386= | Silent (SNP) | VAF 35/86 reads (41%) | catalogued as COSV100599975; called by muse, mutect2, varscan2
- LRP2 | c.9192G>A p.L3064= | Silent (SNP) | VAF 37/124 reads (30%) | catalogued as COSV55551575, COSV99790349; called by muse, mutect2, varscan2
- MAGEC1 | c.1911A>G p.P637= | Silent (SNP) | VAF 72/444 reads (16%) | catalogued as COSV99596619; called by muse, mutect2, varscan2
- MAP4K1 | c.510C>T p.L170= | Silent (SNP) | VAF 6/24 reads (25%) | catalogued as COSV101204427; called by muse, mutect2, varscan2
- METTL7A | c.93A>T p.I31= | Silent (SNP) | VAF 5/98 reads (5%) | catalogued as COSV100153730; called by muse, mutect2
- MEX3D | c.849G>C p.R283= | Silent (SNP) | VAF 15/36 reads (42%) | catalogued as COSV101183549; called by muse, mutect2, varscan2
- MID2 | c.364C>A p.R122= | Silent (SNP) | VAF 7/61 reads (11%) | catalogued as rs372849069, COSV99465675, COSV99465712; called by muse, mutect2, varscan2
- MYF5 | c.123G>A p.A41= | Silent (SNP) | VAF 3/36 reads (8%) | catalogued as COSV99953422; called by muse, mutect2
- MYT1 | c.2511C>A p.A837= | Silent (SNP) | VAF 99/381 reads (26%) | catalogued as rs1338911823, COSV100115515; called by muse, mutect2, varscan2
- NAGS | c.489C>T p.F163= | Silent (SNP) | VAF 3/23 reads (13%) | catalogued as COSV99518042; called by muse, mutect2
- NLRC3 | c.1116C>T p.L372= | Silent (SNP) | VAF 29/79 reads (37%) | catalogued as COSV100073455; called by muse, mutect2, varscan2
- NLRC5 | c.1011G>A p.L337= | Silent (SNP) | VAF 15/144 reads (10%) | catalogued as COSV99348305; called by muse, mutect2, varscan2
- NSL1 | c.180C>G p.L60= | Silent (SNP) | VAF 16/359 reads (4%) | catalogued as COSV100875280; called by muse, mutect2
- NUTM2F | c.1995C>G p.L665= | Silent (SNP) | VAF 6/10 reads (60%) | catalogued as COSV53559332; called by mutect2, varscan2
- OR2C3 | c.12A>T p.I4= | Silent (SNP) | VAF 3/44 reads (7%) | catalogued as COSV100825797; called by muse, mutect2
- OR2T12 | c.576C>G p.V192= | Silent (SNP) | VAF 6/122 reads (5%) | catalogued as COSV100528009; called by muse, mutect2
- OR51E1 | c.867C>G p.L289= | Silent (SNP) | VAF 11/101 reads (11%) | catalogued as COSV101211561, COSV67809579; called by muse, mutect2, varscan2
- OR8H3 | c.24A>T p.T8= | Silent (SNP) | VAF 30/164 reads (18%) | catalogued as COSV100539158; called by muse, mutect2
- OSBPL11 | c.1245C>A p.I415= | Silent (SNP) | VAF 14/190 reads (7%) | catalogued as COSV99954535; called by muse, mutect2
- PAPPA | c.3579G>A p.Q1193= | Silent (SNP) | VAF 37/95 reads (39%) | catalogued as COSV100074384, COSV60282826; called by muse, mutect2, varscan2
- PLEKHM3 | c.378G>A p.R126= | Silent (SNP) | VAF 13/149 reads (9%) | catalogued as COSV101216722, COSV66818566; called by muse, mutect2
- POMT2 | c.750C>A p.I250= | Silent (SNP) | VAF 37/118 reads (31%) | catalogued as COSV99836718; called by muse, mutect2, varscan2
- PTPRT | c.900G>T p.V300= | Silent (SNP) | VAF 8/47 reads (17%) | catalogued as COSV100630685; called by muse, mutect2, varscan2
- RIPK2 | c.417T>C p.T139= | Silent (SNP) | VAF 56/149 reads (38%) | catalogued as COSV99610140; called by muse, mutect2, varscan2
- RPRD1B | c.951C>G p.P317= | Silent (SNP) | VAF 10/107 reads (9%) | catalogued as rs746139376, COSV100987328; called by muse, mutect2, varscan2
- SERPINB4 | c.309C>A p.I103= | Silent (SNP) | VAF 39/196 reads (20%) | catalogued as COSV100346014, COSV100346035; called by muse, mutect2, varscan2
- SHCBP1L | c.1551T>A p.A517= | Silent (SNP) | VAF 80/161 reads (50%) | catalogued as COSV100841091; called by muse, mutect2, varscan2
- SIGLEC1 | c.3010C>T p.L1004= | Silent (SNP) | VAF 12/34 reads (35%) | catalogued as rs1453501155, COSV52473625, COSV99171085; called by muse, mutect2, varscan2
- SLC45A1 | c.27G>T p.P9= | Silent (SNP) | VAF 31/131 reads (24%) | catalogued as rs746109782, COSV57096568, COSV99239282; called by muse, mutect2, varscan2
- SLCO5A1 | c.2308C>A p.R770= | Silent (SNP) | VAF 28/108 reads (26%) | catalogued as COSV52656995, COSV99481084; called by muse, mutect2, varscan2
- SNRNP200 | c.4836G>A p.T1612= | Silent (SNP) | VAF 33/92 reads (36%) | catalogued as rs1428606912, COSV100108071; called by muse, mutect2, varscan2
- SORCS1 | c.2871C>A p.V957= | Silent (SNP) | VAF 12/67 reads (18%) | catalogued as COSV53900326; called by muse, mutect2, varscan2
- SPHKAP | c.2976G>C p.V992= | Silent (SNP) | VAF 20/93 reads (22%) | catalogued as COSV100763717, COSV100764550, COSV60877666; called by muse, mutect2, varscan2
- SPINK4 | c.260G>A p.*87= | Silent (SNP) | VAF 10/22 reads (45%) | catalogued as COSV101121888; called by muse, mutect2, varscan2
- STAB1 | c.5454C>A p.T1818= | Silent (SNP) | VAF 9/159 reads (6%) | catalogued as COSV100195499; called by muse, mutect2
- SYCP2L | c.537T>C p.H179= | Silent (SNP) | VAF 17/57 reads (30%) | catalogued as COSV99305883; called by muse, mutect2, varscan2
- TBRG4 | c.1188G>A p.K396= | Silent (SNP) | VAF 14/72 reads (19%) | catalogued as COSV99345674; called by muse, varscan2
- THRAP3 | c.1707C>A p.V569= | Silent (SNP) | VAF 36/94 reads (38%) | catalogued as COSV100663633; called by muse, mutect2, varscan2
- THSD7B | c.2562A>G p.T854= | Silent (SNP) | VAF 16/55 reads (29%) | catalogued as COSV99758419; called by muse, mutect2, varscan2
- TLR8 | c.2784C>A p.I928= (on ENST00000218032 / NM_138636.5; = p.I946= on NM_016610.4) | Silent (SNP) | VAF 31/107 reads (29%) | catalogued as COSV99487320; called by muse, mutect2, varscan2
- TMEM132B | c.1686C>A p.S562= | Silent (SNP) | VAF 8/73 reads (11%) | catalogued as COSV100171042, COSV54765993; called by muse, mutect2, varscan2
- TMEM86A | c.525A>C p.T175= | Silent (SNP) | VAF 8/72 reads (11%) | catalogued as COSV99773876; called by muse, mutect2, varscan2
- TNFRSF13C | c.465C>A p.T155= | Silent (SNP) | VAF 5/107 reads (5%) | called by muse, mutect2
- TSPYL4 | c.819A>G p.E273= | Silent (SNP) | VAF 6/50 reads (12%) | catalogued as COSV100127296; called by muse, mutect2, varscan2
- UGT1A3 | c.333C>T p.F111= | Silent (SNP) | VAF 50/190 reads (26%) | catalogued as COSV100531092; called by muse, mutect2, varscan2
- USP54 | c.2946G>A p.E982= | Silent (SNP) | VAF 11/52 reads (21%) | catalogued as COSV100357261; called by muse, mutect2, varscan2
- ZXDB | c.1617G>A p.L539= | Silent (SNP) | VAF 19/89 reads (21%) | catalogued as COSV100886070; called by muse, mutect2, varscan2
- C1orf220 | n.740C>G | RNA (SNP) | VAF 8/75 reads (11%) | called by muse, mutect2, varscan2
- CABYR | c.*133G>A | 3'UTR (SNP) | VAF 16/95 reads (17%) | catalogued as rs1468758049, COSV100112810; called by muse, mutect2, varscan2
- CNIH3 | c.*2G>T | 3'UTR (SNP) | VAF 15/111 reads (14%) | catalogued as COSV99686169, COSV99686270; called by muse, mutect2, varscan2
- COP1 | c.2133+18525G>C | Intron (SNP) | VAF 64/124 reads (52%) | catalogued as COSV100443955; called by muse, mutect2, varscan2
- FOXF1 | c.*1G>C | 3'UTR (SNP) | VAF 8/48 reads (17%) | catalogued as COSV99296777; called by muse, mutect2, varscan2
- LINC01565 | n.1047C>A | RNA (SNP) | VAF 12/48 reads (25%) | called by muse, mutect2, varscan2
- LINC02694 | n.37C>A | RNA (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100601952; called by muse, mutect2, varscan2
- LINC02694 | n.38C>A | RNA (SNP) | VAF 20/73 reads (27%) | catalogued as COSV100601955; called by muse, mutect2, varscan2
- RUSC1 | c.-86-281C>G | Intron (SNP) | VAF 12/20 reads (60%) | catalogued as COSV52740082, COSV99429874, COSV99430304; called by muse, mutect2, varscan2
- SCML4 | c.157-5818C>A | Intron (SNP) | VAF 13/51 reads (25%) | catalogued as COSV100940492; called by muse, mutect2, varscan2
- SLC25A3 | c.645-302C>G | Intron (SNP) | VAF 17/156 reads (11%) | catalogued as COSV99499665; called by muse, mutect2
- SLC6A20 | c.*1G>T | 3'UTR (SNP) | VAF 6/58 reads (10%) | catalogued as COSV100653993; called by muse, mutect2
- SSPOP | n.6555C>A | RNA (SNP) | VAF 22/37 reads (59%) | catalogued as COSV100023035; called by muse, mutect2, varscan2
